Somatic mutation profile of cancer-model specimen HCM-WCMC-0749-C34-85A (3D Organoid, passage 11; aliquot HCM-WCMC-0749-C34-85A-01D-A87L-36), derived from the primary tumor of HCMI case HCM-WCMC-0749-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Bronchio-alveolar carcinoma, mucinous; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 72.6 years (26,530 days).
Specimen HCM-WCMC-0749-C34-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 11.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1f21c92-2575-4859-93c7-e5766604eb6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0749-C34-10A (Blood Derived Normal), aliquot HCM-WCMC-0749-C34-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47eda701-bcad-4353-8531-4c7d6fe56266

The open-access MAF lists 92 somatic variants for this specimen: 73 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 16, Nonsense Mutation 5, Frame Shift Del 3, Intron 3, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 120/121 reads (99%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.452C>G p.P151R | Missense Mutation (SNP) | VAF 306/306 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057520000, COSV52677206, COSV52707835, COSV52811105; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACOX3 | c.1927G>A p.V643M | Missense Mutation (SNP) | VAF 183/361 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs771510910, COSV62712160; called by muse, mutect2, varscan2
- ACTL9 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 267/547 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs782721280, COSV61006019; called by muse, mutect2, varscan2
- ARSB | c.1212G>A p.P404= | Splice Region (SNP) | VAF 118/225 reads (52%) | catalogued as rs143071401; called by muse, mutect2, varscan2
- BRINP2 | c.1905G>T p.W635C | Missense Mutation (SNP) | VAF 143/427 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV64181003; called by muse, mutect2, varscan2
- C11orf87 | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 245/562 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as rs746570507; called by muse, mutect2, varscan2
- CILP2 | c.2123G>A p.R708H | Missense Mutation (SNP) | VAF 299/596 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs775642324; called by muse, mutect2, varscan2
- DCAF12L1 | c.630C>A p.S210R | Missense Mutation (SNP) | VAF 352/352 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100948382, COSV64422747; called by muse, mutect2, varscan2
- EPHA5 | c.2539C>T p.P847S | Missense Mutation (SNP) | VAF 115/249 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56630335; called by muse, mutect2, varscan2
- EVC2 | c.2479C>T p.R827C | Missense Mutation (SNP) | VAF 42/420 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.543); catalogued as rs373953980; called by muse, mutect2
- GABRA4 | c.1045del p.E349Kfs*36 | Frame Shift Del (DEL) | VAF 122/376 reads (32%) | catalogued as COSV51927022; called by mutect2, pindel, varscan2
- GRM4 | c.2572C>A p.R858S | Missense Mutation (SNP) | VAF 197/616 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.451); catalogued as rs145173138, COSV65214228; called by muse, mutect2, varscan2
- HPRT1 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 284/284 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV100053104; called by muse, mutect2, varscan2
- JAK1 | c.2679G>T p.R893S | Missense Mutation (SNP) | VAF 177/358 reads (49%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs778030565; called by muse, mutect2, varscan2
- KRTAP1-1 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 289/290 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs772154453; called by muse, mutect2, varscan2
- LRP1B | c.13610C>T p.A4537V | Missense Mutation (SNP) | VAF 137/316 reads (43%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.939); catalogued as rs376526778, COSV67255727; called by muse, mutect2, varscan2
- MYT1 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 402/403 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1262501301, COSV100114942; called by muse, mutect2, varscan2
- NKX2-1 | c.522C>G p.Y174* | Nonsense Mutation (SNP) | VAF 268/585 reads (46%) | catalogued as CD1310890, CM146073; called by muse, mutect2, varscan2
- NKX2-1 | c.204C>A p.Y68* | Nonsense Mutation (SNP) | VAF 281/594 reads (47%) | catalogued as CM120082; called by muse, mutect2, varscan2
- OR14J1 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 162/511 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as COSV65845587; called by muse, mutect2, varscan2
- OR2T1 | c.368T>A p.V123E | Missense Mutation (SNP) | VAF 339/747 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV100822261; called by muse, mutect2, varscan2
- OR56B4 | c.428C>A p.T143N | Missense Mutation (SNP) | VAF 153/320 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs1262031547; called by muse, mutect2, varscan2
- OXTR | c.1079C>T p.T360M | Missense Mutation (SNP) | VAF 212/396 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs199856198; called by muse, mutect2, varscan2
- RTKN2 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 163/330 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1256537620; called by muse, mutect2
- SDK1 | c.6551C>A p.P2184Q | Missense Mutation (SNP) | VAF 308/638 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs762533739; called by mutect2, varscan2
- TTN | c.79963G>C p.D26655H (on ENST00000591111; = p.D19231H on NM_003319.4) | Missense Mutation (SNP) | VAF 164/327 reads (50%) | PolyPhen probably damaging (0.971); catalogued as COSV60327541; called by muse, mutect2, varscan2
- UBN2 | c.1129G>A p.G377S | Missense Mutation (SNP) | VAF 143/342 reads (42%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs368430654; called by muse, mutect2, varscan2
- UNC13B | c.4298C>G p.P1433R | Missense Mutation (SNP) | VAF 96/96 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100266718, COSV100266773; called by muse, mutect2, varscan2
- WWC1 | c.1628C>G p.P543R | Missense Mutation (SNP) | VAF 350/650 reads (54%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.89); catalogued as rs751993520; called by muse, mutect2, varscan2
- ZNF804A | c.3526G>A p.V1176I | Missense Mutation (SNP) | VAF 158/334 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs767120954, COSV56442498, COSV56462276; called by muse, mutect2, varscan2
- ZNF99 | c.2299G>C p.G767R | Missense Mutation (SNP) | VAF 135/332 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101233779; called by muse, mutect2, varscan2
- ATR | c.6619T>A p.S2207T | Missense Mutation (SNP) | VAF 93/209 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- BMPER | c.1605C>A p.N535K | Missense Mutation (SNP) | VAF 182/353 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- BTBD11 | c.2917T>A p.F973I (on ENST00000280758 / NM_001018072.2; = p.F510I on NM_001017523.2) | Missense Mutation (SNP) | VAF 38/253 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCNE1 | c.1222G>T p.E408* | Nonsense Mutation (SNP) | VAF 189/404 reads (47%) | called by muse, mutect2
- CDH13 | c.673C>A p.L225I | Missense Mutation (SNP) | VAF 134/296 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHL1 | c.2716_2718delinsAATA p.P906Nfs*12 (on ENST00000397491 / NM_001253387.1; = p.P922Nfs*12 on NM_006614.4) | Frame Shift Ins (INS) | VAF 65/171 reads (38%) | called by pindel, varscan2*
- COBLL1 | c.2297_2300del p.D766Gfs*11 (on ENST00000392717; = p.D728Gfs*11 on NM_014900.5) | Frame Shift Del (DEL) | VAF 87/227 reads (38%) | called by mutect2, pindel, varscan2
- CX3CL1 | c.398G>A p.G133D | Missense Mutation (SNP) | VAF 288/527 reads (55%) | SIFT tolerated (0.41); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- DACH1 | c.1214del p.P405Lfs*30 | Frame Shift Del (DEL) | VAF 155/403 reads (38%) | called by mutect2, pindel, varscan2
- DDB1 | c.3092G>T p.G1031V | Missense Mutation (SNP) | VAF 143/287 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM104A | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 499/499 reads (100%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- HEATR5B | c.2506G>T p.G836C | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- HERC2 | c.13180C>T p.Q4394* | Nonsense Mutation (SNP) | VAF 125/387 reads (32%) | called by muse, mutect2, varscan2
- HEYL | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 186/481 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HPF1 | c.589A>G p.R197G | Missense Mutation (SNP) | VAF 135/370 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGFL4 | c.257C>A p.T86K | Missense Mutation (SNP) | VAF 201/417 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KCNB2 | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 208/208 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- MAGEL2 | c.2014G>T p.G672C | Missense Mutation (SNP) | VAF 348/718 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MDM2 | c.1304G>C p.S435T | Missense Mutation (SNP) | VAF 124/358 reads (35%) | SIFT tolerated (0.8); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- MS4A3 | c.146A>T p.Q49L | Missense Mutation (SNP) | VAF 121/217 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- NEK10 | c.1789A>T p.N597Y | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- PCDHGA1 | c.1482C>A p.D494E | Missense Mutation (SNP) | VAF 176/374 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- PDE4D | c.1933C>T p.Q645* (on ENST00000340635 / NM_001104631.2; = p.Q509* on NM_006203.4) | Nonsense Mutation (SNP) | VAF 200/394 reads (51%) | called by muse, mutect2, varscan2
- PHLDB3 | c.1830A>T p.E610D | Missense Mutation (SNP) | VAF 17/504 reads (3%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.642); called by muse, mutect2
- PLPPR4 | c.343C>A p.P115T | Missense Mutation (SNP) | VAF 152/298 reads (51%) | SIFT tolerated (0.7); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- POLR3GL | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 112/353 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.096); called by muse, varscan2
- PPP1R3A | c.1130G>A p.S377N | Missense Mutation (SNP) | VAF 115/204 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PRKCH | c.394G>C p.V132L | Missense Mutation (SNP) | VAF 101/220 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PRR32 | c.293C>G p.A98G | Missense Mutation (SNP) | VAF 296/297 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- PTCH1 | c.2644C>A p.L882I | Missense Mutation (SNP) | VAF 41/537 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); called by muse, mutect2
- RAI1 | c.2580C>A p.S860R | Missense Mutation (SNP) | VAF 50/356 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SELL | c.575C>A p.T192N (on ENST00000650983; = p.T179N on NM_000655.5) | Missense Mutation (SNP) | VAF 203/316 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SH3D19 | c.1003A>G p.T335A | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SLC27A6 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 129/270 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SMG7 | c.56T>A p.M19K | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by mutect2, varscan2
- SOD3 | c.455G>T p.R152L | Missense Mutation (SNP) | VAF 264/538 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.293); called by muse, varscan2
- SP8 | c.839T>A p.M280K (on ENST00000361443 / NM_198956.4; = p.M298K on NM_182700.6) | Missense Mutation (SNP) | VAF 308/582 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.117); called by mutect2, varscan2
- SPTA1 | c.6324G>T p.Q2108H | Missense Mutation (SNP) | VAF 181/579 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- TAX1BP1 | c.1704A>C p.E568D | Missense Mutation (SNP) | VAF 131/263 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- TTC7A | c.454A>T p.M152L | Missense Mutation (SNP) | VAF 191/490 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBA6 | c.710A>T p.H237L | Missense Mutation (SNP) | VAF 109/224 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ABCA13 | c.5043G>A p.Q1681= | Silent (SNP) | VAF 132/299 reads (44%) | called by muse, mutect2, varscan2
- ADAMTS18 | c.189T>C p.F63= | Silent (SNP) | VAF 46/265 reads (17%) | called by muse, mutect2, varscan2
- ARHGEF40 | c.4290C>T p.A1430= | Silent (SNP) | VAF 263/565 reads (47%) | catalogued as rs1354383756; called by muse, mutect2, varscan2
- COG7 | c.1311C>T p.T437= | Silent (SNP) | VAF 111/239 reads (46%) | called by muse, mutect2, varscan2
- DDX3Y | c.1663T>C p.L555= | Silent (SNP) | VAF 93/93 reads (100%) | called by muse, mutect2, varscan2
- FSCB | c.1113A>T p.P371= | Silent (SNP) | VAF 198/399 reads (50%) | called by muse, mutect2, varscan2
- GFER | c.52C>T p.L18= | Silent (SNP) | VAF 47/672 reads (7%) | called by muse, mutect2
- HLCS | c.1617G>T p.P539= | Silent (SNP) | VAF 177/403 reads (44%) | catalogued as COSV60794023; called by muse, mutect2, varscan2
- MMP26 | c.138G>A p.S46= | Silent (SNP) | VAF 32/486 reads (7%) | catalogued as rs755146432, COSV56173276; called by muse, mutect2
- RAVER1 | c.993G>T p.L331= | Silent (SNP) | VAF 210/479 reads (44%) | called by muse, mutect2, varscan2
- RNF169 | c.486C>T p.A162= | Silent (SNP) | VAF 160/305 reads (52%) | catalogued as rs777876455; called by muse, mutect2, varscan2
- ROBO4 | c.1914C>T p.A638= | Silent (SNP) | VAF 180/354 reads (51%) | catalogued as rs1320320649; called by muse, mutect2, varscan2
- RYR2 | c.12189G>A p.T4063= | Silent (SNP) | VAF 188/417 reads (45%) | catalogued as rs368948386; called by muse, mutect2, varscan2
- S1PR2 | c.1017C>T p.H339= | Silent (SNP) | VAF 221/535 reads (41%) | called by muse, mutect2, varscan2
- STARD9 | c.573T>C p.H191= | Silent (SNP) | VAF 55/55 reads (100%) | called by muse, mutect2, varscan2
- UNC13A | c.1506C>T p.L502= | Silent (SNP) | VAF 147/345 reads (43%) | catalogued as rs759140176; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1047-3103G>A | Intron (SNP) | VAF 28/409 reads (7%) | catalogued as rs569857013; called by muse, mutect2
- CCDC158 | c.1029+3605C>T | Intron (SNP) | VAF 137/283 reads (48%) | called by muse, mutect2, varscan2
- CEP89 | c.39+286C>T | Intron (SNP) | VAF 172/359 reads (48%) | catalogued as rs1016700301; called by muse, mutect2, varscan2
